Surgical pathology report (de-identified scan), TCGA case TCGA-90-7769, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site ABS - IUPUI, specimen TCGA-90-7769-01A (Primary Tumor).

[page 1 of 4]
Operative Procedure:
Right thoracotomy, pneumonectomy

Specimen Received:
A: Left paratracheal LN
B: Inferior pulmonary ligament LN
C: Lymph node: Parat [REDACTED]
D: Lymph node: High
E: Right lung
F: Carinal margin [REDACTED]
G: Subcarinal lymph nodes

Final Pathologic Diagnosis:
A. Lymph node, left paratracheal, excision:
One lymph node, negative for tumor (0/1)

B. Lymph node, inferior pulmonary ligament, excision:
One lymph node, negative for tumor (0/1)

C. Lymph node, paratracheal #2, excision:
Eighteen lymph nodes, negative for tumor (0/18)

D. Lymph node, high paratracheal 2R, excision:
One lymph node, negative for tumor (0/1)

E. Lung, right, resection:
Squamous cell carcinoma. See cancer synoptic report.

Specimen: Right lung
Procedure: Pneumonectomy
Specimen laterality: Right
Tumor site: Hilum
Specimen integrity: Intact
Tumor size: 6.4 cm (greatest dimension)
Tumor focality: Single mass involving upper, middle, and lower lobe
Tumor histologic type: Squamous cell carcinoma
Tumor grade: Moderately differentiated
Visceral pleura invasion: Not identified
Tumor extension: Extension into hilar area
Margins:
Bronchial margin: Uninvolved by invasive carcinoma
Vascular margin: Soft tissue adjacent to blood vessel which is involved by invasive carcinoma
Parenchymal margin: Not applicable
Parietal pleural margin: Not applicable
Chest wall margin: Cannot be assessed

[page 2 of 4]
Other attached tissue margin: Not applicable

Treatment effect: Not applicable

Lymph-vascular invasion: Present

Pathologic Staging (pTNM):

TNM Descriptors: None

Primary tumor (pT): pT2b

Regional lymph nodes (pN): pN1

Number examined: 32

Number involved: 1

If lymph node(s) involved, specify involved nodal station(s):

Peribronchial

Distant metastasis (pM): pMx

Additional pathologic findings: Emphysema

F. Lung, carina margin, excision:

Negative for tumor

Frozen section diagnosis confirmed

G. Lymph node, subcarinal, excision:

Seven lymph nodes, negative for tumor (0/7)

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Intraoperative Consult Diagnosis:

FSF Carina margin:

Negative.

FS TAT: 19 mins.

Gross Description:

Received are seven containers labeled with the patient's name.

Part A is received in formalin and is additionally labeled "left paratracheal lymph node." The specimen consists of a gray-tan probable lymph node received with some associated fat which has a greatest dimension of 1.4 cm. The lymph node is trisected and entirely submitted in cassette A.

Part B is received in formalin and is additionally labeled "inferior pulmonary ligament lymph node." The specimen consists of a gray-tan probable lymph node received with some associated fat which has a greatest dimension of 0.7 cm. The lymph node is submitted in toto in cassette B.

Part C is received in formalin and is additionally labeled "paratracheal lymph node #2." The specimen consists of an aggregate of irregular, ragged, gray-yellow, lobulated fat which has dimensions 6 x 4 x 1.6 cm. An exhaustive

[page 3 of 4]
search of the fat reveals 17 probable lymph node that range from 0.4 to 2.2 cm in greatest dimension. The lymph nodes are submitted as labeled:

- C1: Five lymph nodes submitted in toto
- C2: Six lymph nodes submitted in toto
- C3: Five lymph nodes submitted in toto
- C4: Representative section of the largest lymph node

Part D is received in formalin and is additionally labeled "high paratracheal 2R lymph node." The specimen consists of a gray-tan probable lymph node received with some associated fat which has a greatest dimension of 1.5 cm. The lymph node is bisected and entirely submitted in cassette D.

Part E is received in formalin (some tissue has been submitted fresh to the Tissue Bank) and is additionally labeled "right lung." The specimen consists of a right lung with the usual three lobation which has a weight of 498 g and dimensions of 20.4 x 7.9 x 8.8 cm. The pleura is gray-purple to black, lobulated and glistening with focal anthracotic pigmentation throughout. The hilar structures are identified with the bronchus open and the vessels ligated. Some of the soft tissue at the hilum is granular and cauterized. This cauterized surface is inked blue. The specimen is serially sectioned to reveal a gray-white, granular, focally friable, indurated mass at the hilum which has dimensions of 6.4 x 4.6 x 3.9 cm. This mass extends to within 0.3 cm of the bronchial margin. This mass extends to within 0.1 cm of the new inked cauterized surface at the hilum. This mass involves the upper, middle and lower lobes. This mass extends to within 1 mm of the pleural surface. Additionally, this mass markedly compresses and superficially invades the vessels at the hilum. The lung parenchyma outside of the area of the mass is gray-tan to red-brown, spongy with some peripheral consolidation. The bronchi and vessels distal to the mass are somewhat dilated. The bronchi contain thick, gray-green mucus. There is some bronchiectasis present. Also, there is a confluence of grossly positive, extraparenchymal, peribronchial lymph nodes present which has dimensions of 3 x 1.6 x 0.7 cm. Representative sections are submitted as labeled:

- E1: Bronchial margin
- E2: Vascular margin
- E3: Mass to blue inked cauterized surface at the hilum
- E4: Mass to upper lobe
- E5: Mass to lower lobe
- E6: Mass to lower lobe
- E7: Mass to lower lobe to include pleura
- E8: Mass to include compressed and superficially invaded vessels
- E9: Bronchiectasis and consolidation
- E10: Normal most lung parenchyma
- E11: Confluence of grossly positive lymph nodes

Part F is received fresh for intraoperative consultation and is additionally labeled "carina margin." The specimen consists of two irregular, gray-tan fibrocartilaginous tissues which have dimensions of 1 x 0.8 x 0.6 cm and 2.4 x 0.6 x 0.4 cm. Representative sections have been submitted for frozen section diagnosis and the residue resubmitted for permanent sections in cassette F1.

[page 4 of 4]
While additional representative sections are submitted in cassette F2.

Part G is received in formalin and is additionally labeled "subcarinal lymph nodes." The specimen consists of a portion of irregular, ragged, gray-yellow, lobulated fat which has dimensions of 4.6 x 3.2 x 2.2 cm. This fat is serially sectioned to reveal a confluence of gray-tan to brown-black lymph nodes. These lymph nodes are somewhat indurated and are grossly suspicious for metastasis. Representative sections are submitted in cassettes G1 and G2.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

Source: NCI Genomic Data Commons file f326ae52-e3c6-4810-b703-6aa91ccc414d (TCGA-90-7769.251DF531-37E8-4728-92E4-3345F72685DC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).